Somatic mutation profile of tumor specimen TARGET-30-PATHJU-09A (aliquot TARGET-30-PATHJU-09A-01D) from TARGET case TARGET-30-PATHJU, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.7 years (998 days).
Specimen TARGET-30-PATHJU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b5aec9f5-efef-44c1-ad65-264bfe7bb855.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PATHJU-10A (Blood Derived Normal), aliquot TARGET-30-PATHJU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85d83d74-8d10-41ae-b3a4-010a81e7059c

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3522C>A p.F1174L | Missense Mutation (SNP) | VAF 30/82 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.641); catalogued as rs863225281, COSV66555460, COSV66556325; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PLXNB1 | c.3635C>A p.S1212* | Nonsense Mutation (SNP) | VAF 18/34 reads (53%) | catalogued as COSV56493103; called by muse, mutect2, varscan2
